MMRF case MMRF_1491 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/cded9579-0f99-483f-9358-fc88d358d67d

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 55 years; Vital status: Dead; Days to death: 404 days (1.1 years); Cause of death: Not Cancer Related.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 55.6 years (20,309 days); ISS stage: II; Days to last known disease status: 404 days (1.1 years); Days to last follow up: 404 days (1.1 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 179 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 193 days; Days to treatment end: 193 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 234 days; Days to treatment end: 234 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 235 days; Days to treatment end: 235 days.
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 390 days (1.1 years); Days to treatment end: 397 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 404.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -5 (ECOG 1): M Protein 3.93 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 8.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1930 mg/dL; Immunoglobulin G 49.1 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 3.92 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 153 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 9.5 g/dL; Glucose 5.83 mmol/L.
- Day 92 (ECOG 1): M Protein 0.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.904 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 111 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.08 g/L; Beta 2 Microglobulin 1.74 µg/mL; Lactate Dehydrogenase 3.23 µkat/L; Hemoglobin 5.95 mmol/L; Leukocytes 1.4 ×10⁹/L; Absolute Neutrophil 1 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 55.7 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.03 mmol/L; Albumin 35 g/L; Total Protein 5.7 g/dL; Glucose 19.2 mmol/L.
- Day 162 (ECOG 2): M Protein 0.94 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.386 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 138 mg/dL; Immunoglobulin G 11.7 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.28 µkat/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.1 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 98 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.03 mmol/L; Total Protein 5.9 g/dL.
- Day 261 (ECOG 1): Lactate Dehydrogenase 10.2 µkat/L; Hemoglobin 6.01 mmol/L; Leukocytes 1.9 ×10⁹/L; Absolute Neutrophil 1.1 ×10⁹/L; Platelets 31 ×10⁹/L; Creatinine 50.4 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 1.93 mmol/L; Albumin 26 g/L; Total Protein 5 g/dL; Glucose 6.88 mmol/L.
- Day 390 (ECOG 1): M Protein 1.96 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.408 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 294 mg/dL; Immunoglobulin G 24.7 g/L; Immunoglobulin A 0.22 g/L; Immunoglobulin M 2.9 g/L; Lactate Dehydrogenase 5.17 µkat/L; Hemoglobin 6.94 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 73 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.45 mmol/L; Albumin 37 g/L; Total Protein 7.6 g/dL; Glucose 10.1 mmol/L.

Other clinical attributes
- Day -5: Weight: 84 kg; Height: 157 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.

Biospecimens (2 samples)
- Sample MMRF_1491_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -5 days.
- Sample MMRF_1491_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -5 days.
